MMRF case MMRF_1749 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3bb63cee-c121-4903-9408-64e5b32152c7

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.7 years (19,264 days); ISS stage: II; Days to last known disease status: 1,107 days (3.0 years); Days to last follow up: 1,107 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 145 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 231 days; Days to treatment end: 953 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 231 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 596 days (1.6 years); Days to treatment end: 617 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 8.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 96.4 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 5.2 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.51 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 31 g/L; Total Protein 13.6 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 85 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.935 mg/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.14 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.55 mmol/L.
- Day 182 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.715 mg/dL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.41 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 48 g/L; Total Protein 6.6 g/dL; Glucose 7.21 mmol/L.
- Day 287 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.49 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 7.43 mmol/L.
- Day 371 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.783 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 5.68 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 8.03 mmol/L.
- Day 455 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.641 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.802 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 5.72 mmol/L.
- Day 532 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 9.01 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.94 mmol/L.
- Day 644 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.241 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.34 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 6.22 mmol/L.
- Day 728 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.744 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 3.94 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 6.16 mmol/L.
- Day 826 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.656 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 7.25 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.47 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 4.57 mmol/L.
- Day 938 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.753 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.561 mg/dL; Immunoglobulin G 3.97 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 4.15 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 7.48 mmol/L.
- Day 1,022 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.405 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.252 mg/dL; Immunoglobulin G 4.15 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3.24 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 6.99 mmol/L.
- Day 1,107 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.881 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.647 mg/dL; Immunoglobulin G 3.95 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.53 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 8.8 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lymphoma; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1749_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1749_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
